Somatic mutation profile of tumor specimen TCGA-DD-AADP-01A (aliquot TCGA-DD-AADP-01A-11D-A38X-10) from TCGA case TCGA-DD-AADP, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 45.9 years (16,760 days).
Specimen TCGA-DD-AADP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d37d769-18c2-42cf-9095-6fdafeefc7a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-AADP-10A (Blood Derived Normal), aliquot TCGA-DD-AADP-10A-01D-A38X-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bcb43e3a-aa20-4317-be37-b82c3de22714

The open-access MAF lists 109 somatic variants for this specimen: 88 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 18, Nonsense Mutation 5, Splice Site 4, Intron 3, Frame Shift Del 1, In Frame Del 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.349C>G p.L117V (on ENST00000372530 / NM_001198934.2; = p.L74V on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV99767575; called by muse, mutect2, varscan2
- AKAP6 | c.3689G>T p.S1230I | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99802293; called by muse, mutect2, varscan2
- ANGPTL1 | c.559A>C p.N187H | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.179); catalogued as COSV99328270; called by muse, mutect2, varscan2
- APOBEC3H | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 25/56 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.019); catalogued as rs374311513; called by muse, mutect2, varscan2
- ARAP3 | c.3412-1G>A p.X1138_splice | Splice Site (SNP) | VAF 29/105 reads (28%) | catalogued as COSV99499993; called by muse, mutect2, varscan2
- ARHGAP29 | c.265A>G p.I89V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs766258754, COSV99558520; called by muse, mutect2, varscan2
- ATM | c.8011-2A>T p.X2671_splice | Splice Site (SNP) | VAF 39/70 reads (56%) | catalogued as CS053445, COSV53742315; called by muse, mutect2, varscan2
- ATRIP | c.1451A>G p.H484R | Missense Mutation (SNP) | VAF 24/68 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as COSV99604093; called by muse, mutect2, varscan2
- AXIN1 | c.1645C>T p.Q549* | Nonsense Mutation (SNP) | VAF 30/45 reads (67%) | catalogued as COSV51982920; called by muse, mutect2, varscan2
- BAZ2A | c.200C>T p.S67L | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV51639412, COSV99466857; called by muse, mutect2, varscan2
- BOD1L1 | c.6755G>T p.G2252V | Missense Mutation (SNP) | VAF 30/78 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99239837; called by muse, mutect2, varscan2
- BRINP2 | c.1777T>C p.F593L | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.956); catalogued as rs771351231, COSV100838191; called by muse, mutect2, varscan2
- BTRC | c.937G>A p.D313N (on ENST00000370187 / NM_033637.4; = p.D277N on NM_003939.5) | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1222223712, COSV100927875; called by muse, mutect2, varscan2
- CD163L1 | c.1939C>A p.L647I | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.969); catalogued as COSV100550342, COSV58020178; called by muse, mutect2, varscan2
- CHML | c.1285A>G p.I429V | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.643); catalogued as rs753456268, COSV100087568; called by muse, mutect2, varscan2
- CNTN5 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.68); catalogued as COSV99678890; called by muse, mutect2, varscan2
- DGAT1 | c.1237T>G p.F413V | Missense Mutation (SNP) | VAF 42/83 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); catalogued as COSV100184093; called by muse, mutect2, varscan2
- DNER | c.438A>C p.E146D | Missense Mutation (SNP) | VAF 42/117 reads (36%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.757); catalogued as COSV100519529; called by muse, mutect2, varscan2
- DSEL | c.3478T>C p.S1160P | Missense Mutation (SNP) | VAF 35/101 reads (35%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.997); catalogued as rs535957295, COSV100025864; called by muse, mutect2, varscan2
- EGR3 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.036); catalogued as COSV100416226, COSV57833294; called by muse, mutect2, varscan2
- EIF2A | c.1354A>G p.R452G | Missense Mutation (SNP) | VAF 34/85 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV99856035; called by muse, mutect2, varscan2
- EIF2AK4 | c.4270A>G p.I1424V | Missense Mutation (SNP) | VAF 64/156 reads (41%) | SIFT tolerated (0.29); PolyPhen benign (0.04); catalogued as COSV99774999; called by muse, mutect2, varscan2
- F2 | c.430T>C p.S144P | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0.003); catalogued as COSV100319594; called by muse, mutect2, varscan2
- FANCM | c.4846G>A p.G1616S | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99951280; called by muse, mutect2, varscan2
- FAT2 | c.12074C>T p.A4025V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.42); PolyPhen benign (0.273); catalogued as rs538316910, COSV55819471; called by muse, mutect2, varscan2
- FMN2 | c.1987-1G>A p.X663_splice | Splice Site (SNP) | VAF 170/304 reads (56%) | catalogued as COSV60445544; called by muse, mutect2, varscan2
- GABRG1 | c.722T>C p.V241A | Missense Mutation (SNP) | VAF 58/138 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.411); catalogued as rs1193002288, COSV99778407; called by muse, mutect2, varscan2
- GIT2 | c.37G>C p.D13H | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV99924049; called by muse, varscan2
- HK2 | c.1282C>G p.H428D | Missense Mutation (SNP) | VAF 40/89 reads (45%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.573); catalogued as COSV99309306; called by muse, mutect2, varscan2
- ITGA2B | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 13/34 reads (38%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV99289038; called by muse, mutect2, varscan2
- KAT6A | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated (0.81); PolyPhen possibly damaging (0.477); catalogued as COSV99705467; called by muse, mutect2, varscan2
- KCNJ3 | c.1377A>T p.L459F | Missense Mutation (SNP) | VAF 110/274 reads (40%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.014); catalogued as COSV99716128; called by muse, varscan2
- KIDINS220 | c.344G>A p.G115D | Missense Mutation (SNP) | VAF 95/249 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99876029; called by muse, mutect2, varscan2
- KLF10 | c.245C>G p.P82R | Missense Mutation (SNP) | VAF 67/113 reads (59%) | SIFT tolerated (0.15); PolyPhen benign (0.168); catalogued as COSV99574831; called by muse, mutect2, varscan2
- KRT34 | c.162C>G p.C54W | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.682); catalogued as COSV101222679; called by muse, mutect2, varscan2
- LAMA2 | c.4996C>T p.Q1666* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV101370624; called by muse, mutect2, varscan2
- LTBP1 | c.4372T>G p.Y1458D (on ENST00000404816 / NM_206943.4; = p.Y1132D on NM_000627.4) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99698465; called by muse, mutect2, varscan2
- MAP2 | c.5008C>A p.L1670M | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99560849; called by muse, varscan2
- MAPK9 | c.109C>G p.Q37E | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.922); catalogued as COSV100558459; called by muse, mutect2, varscan2
- MGST2 | c.205A>G p.M69V | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs748417296, COSV99643723; called by muse, mutect2, varscan2
- MIB2 | c.1738G>T p.G580C | Missense Mutation (SNP) | VAF 96/174 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100598977; called by muse, mutect2, varscan2
- MYBL1 | c.1396G>T p.G466C | Missense Mutation (SNP) | VAF 38/191 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as COSV101576571; called by muse, mutect2, varscan2
- MYCN | c.299G>T p.G100V | Missense Mutation (SNP) | VAF 272/729 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.935); catalogued as COSV99808391; called by muse, mutect2, varscan2
- MYLK4 | c.435G>A p.K145= | Splice Region (SNP) | VAF 24/92 reads (26%) | catalogued as COSV99193849; called by muse, mutect2, varscan2
- NBAS | c.6787C>T p.R2263* | Nonsense Mutation (SNP) | VAF 140/377 reads (37%) | catalogued as rs746756510, COSV55733798, COSV55741191; called by muse, mutect2, varscan2
- OR5D14 | c.847G>T p.V283F | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.511); catalogued as COSV100162482; called by muse, mutect2
- OR5I1 | c.661T>C p.F221L | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV56888636; called by muse, mutect2, varscan2
- PBRM1 | c.4129T>G p.S1377A (on ENST00000296302 / NM_001366071.2; = p.S1325A on NM_018313.5) | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV99969697; called by muse, mutect2, varscan2
- PCDH8 | c.139G>A p.G47R | Missense Mutation (SNP) | VAF 26/51 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100131871; called by muse, mutect2, varscan2
- PDE6B | c.1310A>T p.K437M | Missense Mutation (SNP) | VAF 95/282 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV99727970; called by muse, mutect2, varscan2
- PIWIL3 | c.1091A>C p.Q364P | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100177803; called by muse, mutect2, varscan2
- PKHD1 | c.10443G>T p.L3481F | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT tolerated (0.3); PolyPhen benign (0.017); catalogued as COSV100944704; called by muse, mutect2, varscan2
- PLA2G4A | c.553C>T p.R185C | Missense Mutation (SNP) | VAF 35/87 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as rs374028240; called by muse, mutect2, varscan2
- PLXDC2 | c.316C>T p.Q106* | Nonsense Mutation (SNP) | VAF 51/146 reads (35%) | catalogued as COSV101025240; called by muse, mutect2, varscan2
- PPFIA3 | c.1493G>A p.R498Q | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.34); catalogued as rs754546714, COSV100494898, COSV61953215; called by muse, mutect2, varscan2
- PPP1R26 | c.124T>A p.S42T | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV100778111; called by muse, mutect2, varscan2
- PRRX1 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs748836293, COSV99509978; called by muse, mutect2, varscan2
- PRSS36 | c.1471C>A p.H491N | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.32); PolyPhen benign (0.038); catalogued as COSV99191296; called by muse, mutect2, varscan2
- PSMD12 | c.791A>T p.Q264L | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as COSV100635379; called by muse, mutect2, varscan2
- PTPRZ1 | c.4645A>C p.S1549R | Missense Mutation (SNP) | VAF 47/140 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.201); catalogued as COSV101100449; called by muse, mutect2, varscan2
- QRICH1 | c.1972C>T p.P658S | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.212); catalogued as COSV100455098; called by muse, mutect2, varscan2
- RDH16 | c.355A>G p.T119A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV100660145; called by muse, mutect2, varscan2
- RFX7 | c.3889A>G p.I1297V (on ENST00000559447 / NM_001368074.1; = p.I1394V on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100429048; called by muse, mutect2, varscan2
- RSPH10B2 | c.436G>A p.V146M | Missense Mutation (SNP) | VAF 97/466 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.085); catalogued as rs771720978, COSV99786244; called by muse, mutect2, varscan2
- RUNDC3B | c.1361C>G p.S454C | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750557108, COSV100353766; called by muse, mutect2, varscan2
- SCARA5 | c.118T>C p.C40R | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.036); catalogued as COSV100107989, COSV57278160; called by muse, mutect2, varscan2
- SLC30A9 | c.926C>A p.S309Y | Missense Mutation (SNP) | VAF 21/120 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.062); catalogued as COSV100048375, COSV52559364; called by muse, mutect2, varscan2
- SPHK2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.178); catalogued as COSV99709462; called by muse, mutect2, varscan2
- SPIRE2 | c.967C>G p.P323A | Missense Mutation (SNP) | VAF 33/49 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100988878; called by muse, varscan2
- STT3B | c.1036A>C p.K346Q | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.033); catalogued as COSV99854379; called by muse, mutect2, varscan2
- TBC1D32 | c.2817T>G p.D939E | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as COSV99250721; called by muse, mutect2, varscan2
- TCF4 | c.1060T>C p.S354P | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV100610490; called by muse, mutect2, varscan2
- TICAM1 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs377447415, COSV99941162; called by muse, mutect2, varscan2
- TNKS2 | c.3160A>G p.M1054V | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100861125; called by muse, mutect2, varscan2
- TRDN | c.1393A>G p.K465E | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.257); catalogued as COSV100522630; called by muse, mutect2
- UBA6 | c.1013A>C p.K338T | Missense Mutation (SNP) | VAF 88/153 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV100451783; called by muse, mutect2, varscan2
- VSX2 | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 134/373 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as COSV100001687; called by muse, mutect2, varscan2
- XRN2 | c.718G>A p.G240S | Missense Mutation (SNP) | VAF 30/77 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101018488; called by muse, mutect2, varscan2
- YY1AP1 | c.1736G>A p.R579K (on ENST00000295566 / NM_139118.2; = p.R522K on NM_018253.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/221 reads (29%) | SIFT tolerated, low confidence (0.44); PolyPhen possibly damaging (0.455); catalogued as rs1366631618, COSV55125406, COSV99804348; called by muse, mutect2, varscan2
- ZNF536 | c.649C>A p.L217M | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.825); catalogued as COSV100835467; called by muse, mutect2, varscan2
- ZNF536 | c.1929C>G p.Y643* | Nonsense Mutation (SNP) | VAF 34/106 reads (32%) | catalogued as COSV100835468; called by muse, mutect2, varscan2
- ZNF605 | c.1732A>G p.I578V | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs991264746, COSV100053554; called by muse, mutect2, varscan2
- ZNF644 | c.3964A>T p.M1322L (on ENST00000337393 / NM_201269.3; = p.M100L on NM_016620.3) | Missense Mutation (SNP) | VAF 59/134 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.27); catalogued as COSV100494578; called by muse, mutect2, varscan2
- ZNF804A | c.3347_3358del p.A1116_A1119del | In Frame Del (DEL) | VAF 35/94 reads (37%) | catalogued as rs754346637; called by mutect2, varscan2
- ARID1A | c.3389_3398del p.I1130Tfs*28 | Frame Shift Del (DEL) | VAF 27/44 reads (61%) | called by mutect2, pindel, varscan2
- COL11A2 | c.1954_1956dup p.G652dup (on ENST00000341947 / NM_080680.3; = p.G545dup on NM_080679.2) | In Frame Ins (INS) | VAF 20/66 reads (30%) | called by mutect2, pindel, varscan2
- KLHL26 | c.728G>T p.R243L | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.62); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SCAMP4 | c.396-14_400del p.X132_splice | Splice Site (DEL) | VAF 7/21 reads (33%) | called by mutect2, varscan2
- AL662899.2 | c.111T>C p.T37= | Silent (SNP) | VAF 29/78 reads (37%) | catalogued as COSV100789025; called by muse, mutect2, varscan2
- ARMC3 | c.81A>T p.A27= | Silent (SNP) | VAF 23/77 reads (30%) | catalogued as COSV99958494; called by muse, mutect2, varscan2
- CRK | c.111G>A p.V37= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100315688; called by muse, varscan2
- DENND4C | c.5769A>G p.A1923= (on ENST00000434457 / NM_001330640.2; = p.A1874= on NM_017925.7) | Silent (SNP) | VAF 39/74 reads (53%) | catalogued as COSV100194569; called by muse, mutect2, varscan2
- DNAH8 | c.10527C>A p.G3509= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as COSV100545199, COSV100546269; called by muse, mutect2, varscan2
- FAM171A1 | c.1128G>A p.P376= | Silent (SNP) | VAF 28/95 reads (29%) | catalogued as rs149346946; called by muse, mutect2, varscan2
- IARS2 | c.450G>T p.V150= | Silent (SNP) | VAF 169/324 reads (52%) | catalogued as COSV100228441; called by muse, mutect2, varscan2
- ISCA1 | c.111A>G p.Q37= | Silent (SNP) | VAF 29/58 reads (50%) | catalogued as rs998777850, COSV100276504; called by muse, mutect2, varscan2
- LGALS3BP | c.1284A>C p.S428= | Silent (SNP) | VAF 19/46 reads (41%) | catalogued as COSV99431797; called by muse, mutect2, varscan2
- NLRP1 | c.720G>A p.T240= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs369131551, COSV52571602; called by muse, mutect2, varscan2
- OGT | c.780G>T p.V260= | Silent (SNP) | VAF 70/93 reads (75%) | catalogued as COSV101035509; called by muse, mutect2, varscan2
- RBMS3 | c.603T>C p.N201= | Silent (SNP) | VAF 95/282 reads (34%) | catalogued as COSV99822781; called by muse, mutect2, varscan2
- SAMD5 | c.330T>C p.S110= | Silent (SNP) | VAF 13/39 reads (33%) | catalogued as COSV100822514; called by muse, mutect2
- SMCHD1 | c.1281C>T p.I427= | Silent (SNP) | VAF 28/68 reads (41%) | catalogued as COSV99861874, COSV99861995; called by muse, mutect2, varscan2
- SYNE3 | c.444G>A p.E148= | Silent (SNP) | VAF 18/50 reads (36%) | catalogued as COSV62082311; called by muse, mutect2, varscan2
- ZNF33A | c.1371A>G p.V457= (on ENST00000458705 / NM_006974.3; = p.V458= on NM_006954.2) | Silent (SNP) | VAF 30/93 reads (32%) | catalogued as COSV100276003; called by muse, mutect2, varscan2
- ZNF578 | c.285T>C p.S95= | Silent (SNP) | VAF 91/215 reads (42%) | catalogued as COSV101405083; called by muse, mutect2, varscan2
- ZNF7 | c.61C>T p.L21= | Silent (SNP) | VAF 43/159 reads (27%) | catalogued as COSV100295976; called by muse, mutect2, varscan2
- FYB1 | c.1907+1637A>G | Intron (SNP) | VAF 21/85 reads (25%) | catalogued as COSV60944021; called by muse, mutect2, varscan2
- POLR2F | c.453-15477G>A | Intron (SNP) | VAF 25/69 reads (36%) | catalogued as rs1272065884, COSV100329806; called by muse, mutect2, varscan2
- RBPMS2 | c.88-10763T>C | Intron (SNP) | VAF 16/70 reads (23%) | catalogued as COSV100264909; called by muse, mutect2, varscan2
